Gene-level copy-number profile of tumor specimen ALCH-AF4X-TTP1-A from ALCHEMIST case ALCH-AF4X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,223 days).
Specimen ALCH-AF4X-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ec030974-a922-4903-ba6b-45b2e5f71db3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF4X-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/cad8e678-3b00-4a1a-9614-3e25b9547ac9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 11,221; copy number 2: 40,805; copy number 3: 2,074; copy number 4: 3,236; copy number 5: 1,453; copy number 6: 6; copy number 7: 7; copy number 9: 56; copy number 10: 1; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:70,852,353–73,355,253, 23 genes: PTGER3, AL031429.1, AL031429.2, ZRANB2-AS1, ZRANB2, MIR186, ZRANB2-AS2, AL358453.1, NEGR1, AL354949.1, AL359821.1, NEGR1-IT1, GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360.
- chr9:39,886,861–39,892,895, 3 genes: RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene: RPL7AP49.
- chr9:42,183,659–42,626,813, 14 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5.
- chr12:121,804,009–121,832,656, 1 gene: SETD1B.
- chr19:20,432,552–20,571,095, 2 genes (within-gene range 0–1): AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,525 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,838,210–248,937,043, 6 genes, copy number 5–6: ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:90,234,812–90,367,699, 5 genes, copy number 5: IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr6:391,752–39,229,475, 1,114 genes, copy number 5 (broad region; genes not listed).
- chr6:41,636,882–62,286,225, 326 genes, copy number 5 (broad region; genes not listed).
- chr9:60,914,407–60,964,196, 5 genes, copy number 5: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr12:68,552,995–70,920,738, 56 genes, copy number 9: RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr12:71,439,798–71,586,310, 1 gene, copy number 10 (within-gene range 1–10): LGR5.
- chr12:84,448,625–84,913,615, 3 genes, copy number 7–11: AC087888.1, AC093027.1, SLC6A15.
- chr12:88,430,442–88,602,195, 5 genes, copy number 7: Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1.
- chr14:18,333,726–18,341,859, 1 gene, copy number 6: CR383658.1.
- chr21:44,158,740–44,194,338, 3 genes, copy number 6–7: LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 8,380. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
